Somatic mutation profile of tumor specimen 0DSHT2 from CCDI case PBCGUR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pleuropulmonary blastoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 1.2 years (440 days).
Specimen 0DSHT2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3160a2f8-2529-4be3-89be-07c922729ea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSHTB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85f17544-ef6f-4524-9476-643a9b65cdce

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEAF1 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587777408, CM144693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 89/237 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- AR | c.1142C>G p.P381R | Missense Mutation (SNP) | VAF 185/297 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as COSV65964144; called by muse, mutect2, varscan2
- PTPN14 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 182/617 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC22A18AS | c.523T>C p.C175R | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CES3 | c.1425C>T p.D475= | Silent (SNP) | VAF 25/242 reads (10%) | catalogued as rs763953391, COSV100309887; called by muse, mutect2, varscan2
- DPEP3 | c.1251G>A p.A417= | Silent (SNP) | VAF 62/170 reads (36%) | catalogued as rs773421121; called by muse, mutect2, varscan2
- STK32A | c.636G>A p.T212= | Silent (SNP) | VAF 72/277 reads (26%) | catalogued as rs558458515, COSV60419372; called by muse, mutect2, varscan2
- WHRN | c.1176C>T p.G392= | Silent (SNP) | VAF 41/563 reads (7%) | catalogued as rs200276167; ClinVar: likely benign; called by muse, mutect2
